Gene-level copy-number profile of tumor specimen C3L-09227-03 from CPTAC case C3L-09227, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 77.0 years (28,131 days).
Specimen C3L-09227-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 747aeb3b-2b80-4d15-bc84-c38292494c46.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09227-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/6bbb82ca-b1df-4ca8-96ec-a0748c41b2fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 336; copy number 2: 54,013; copy number 3: 685; copy number 4: 3,785; copy number 5: 10; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–157,887, 3 genes: AL627309.7, AL627309.2, RNU6-1100P.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr8:7,190,901–7,200,857, 2 genes: RPS3AP33, AF228730.1.
- chr10:126,988,095–127,026,507, 2 genes (within-gene range 0–2): AL359094.1, AL359094.2.
- chr15:30,516,079–30,614,561, 10 genes: AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P.
- chr16:78,355,529–78,355,834, 1 gene (within-gene range 0–2): LSM3P5.
- chr17:31,303,770–31,321,749, 3 genes (within-gene range 0–2): EVI2B, AC134669.1, EVI2A.
- chr17:43,014,607–43,305,397, 26 genes: VAT1, RND2, BRCA1, RPL21P4, NBR2, AC135721.2, AC135721.1, AC060780.1, BRCA1P1, AC060780.2, NBR1, TMEM106A, CCDC200, RNU2-1, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2.
- chr20:14,547,184–14,758,056, 3 genes (within-gene range 0–2): RNF11P2, MACROD2-IT1, RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–2): AL138808.1, RNU6-1159P, RNU6-115P.
- chr22:24,686,168–24,712,520, 4 genes: ARL5AP4, AP000357.1, AP000358.1, CRIP1P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:587,629–594,768, 1 gene, copy number 5: AC114498.1.
- chr1:631,074–632,616, 2 genes, copy number 5 (within-gene range 2–5): MTCO1P12, AC114498.2.
- chr1:633,535–634,922, 3 genes, copy number 5 (within-gene range 2–5): MTATP8P1, MTATP6P1, MTCO3P12.
- chr11:112,967–139,612, 3 genes, copy number 6 (within-gene range 2–6): AC069287.1, CICP23, LINC01001.
- chr20:64,290,187–64,327,972, 3 genes, copy number 5: CICP4, LINC00266-1, AL137028.1.
- chr21:9,068,361–9,129,752, 1 gene, copy number 5 (within-gene range 4–5): TEKT4P2.

Autosomal genes at a single copy (total copy number 1): 336. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
